TCGA case TCGA-W5-AA2I — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3c8ca064-a4a7-416f-a069-4324d4a72038

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 1,939 days (5.3 years).

Diagnoses (2)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,388 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary of the bladder (histology not recorded by GDC). Age at diagnosis: 67.4 years (24,605 days); Days to diagnosis: 217 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 226 days; Residual disease: R1.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Ablation or Embolization, NOS, for initial diagnosis; Organ Transplantation to Liver, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 1,939 days (5.3 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 296 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 40.
- Total Bilirubin 0.7 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Creatinine 1.4 mg/dL [Blood test normal range lower: 0.9; Blood test normal range upper: 1.4].
- Platelets 138 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Alpha Fetoprotein 2.9 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.2].
- Albumin 4.4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 125 kg; Height: 178 cm; BMI: 39.5.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W5-AA2I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 280 mg.
  Slide TCGA-W5-AA2I-01A-03-TSC: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-W5-AA2I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-W5-AA2I-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-W5-AA2I-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-W5-AA2I-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Definitive surgical procedure: Segmentectomy, Multiple.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: bladder; New tumor event liver transplant: No; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event ablation embolization treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,939 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,939 days; disease-free interval: no event (censored), 1,939 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 217 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-W5-AA2I-01A-32D-A416-01): tumor purity 0.83, ploidy 1.76, whole-genome doublings 0.
